TCGA case TCGA-C5-A2LX — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b82f4c6d-530f-4b0e-8f33-995633cb254a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 54.9 years (20,070 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 39; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 77 days; Days to treatment end: 134 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 77 days; Days to treatment end: 134 days; Treatment dose: 5,120 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.

Follow-up (10 entries)
- Day 31 (preoperative): Days to imaging: 31 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 31 (preoperative): Days to imaging: 31 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 31 (preoperative): Days to imaging: 31 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 31 (preoperative): Days to imaging: 31 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 31 (preoperative): Days to imaging: 31 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 31 (preoperative): Days to imaging: 31 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 52 (prior to adjuvant therapy): ECOG performance status: 1.
- Day 73 (prior to adjuvant therapy): ECOG performance status: 1.
- Days to follow up: 491 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 2,526 days (6.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV16].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 165 cm; BMI: 23.9.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 35; Age at onset: 18.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A2LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-C5-A2LX-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-C5-A2LX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A2LX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 4; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 4; Tobacco smoking history indicator: 2; Performance status timing: Pre-Adjuvant Therapy; Tumor response: Complete response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Margins involved hysterectomy: Positive vaginal margin; Pelvic extension comment: severe squamous dysplasia (CIN3) extending to the vaginal margin of excision; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion: Present; Corpus involvement: Absent; Pcr primer pairs: GP5+/GP6+.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: HPV 16.
- Follow-up form 1: Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Brachytherapy status: Completed as planned; Radiation therapy xrt type: Imrt; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 6; New tumor event diagnosis indicator: No.
- Follow-up form 1, Radiation supplemental: Days from index date to radiation therapy started: 93; Radiation therapy status: Completed as Planned.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,526 days; disease-specific survival: no event (censored), 2,526 days; disease-free interval: no event (censored), 2,526 days; progression-free interval: no event (censored), 2,526 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A2LX-01A-11D-A18H-01): tumor purity 0.61, ploidy 2.77, whole-genome doublings 1.
